Surgical pathology report (de-identified scan), TCGA case TCGA-3N-A9WD, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greenville Health System, specimen TCGA-3N-A9WD-06A (Metastatic).

[page 1 of 2]
PATHOLOGY EXAMINATION

COLLECTED:

CLIENT:

PHYSICIAN:

ADDITIONAL:

COPY TO/NOTES:

NO ADDITIONAL PHYSICIANS

SPECIMEN(S) RECEIVED:

A: (R) superficial parotidectomy

B: Parotid lymph node right

CLINICAL DATA/HISTORY:

History of melanoma with positive SLN bx, status post

Now with local recurrence.

ICD-O-3
Melanoma NOS 8720/3
Site: Parotid lymph node
C77.0
4/21/14

FINAL PATHOLOGIC DIAGNOSIS:

A. RIGHT SUPERFICIAL PAROTIDECTOMY:

- METASTATIC MELANOMA INVOLVING SALIVARY GLAND AND TWO INTRAPARENCHYMAL LYMPH NODES.
- EXTRANODAL EXTENSION PRESENT.
- MARGINS NEGATIVE (MELANOMA LESS THAN 1 MM FROM INKED TISSUE EDGE).

B. PAROTID LYMPH NODE, RIGHT:

- ONE BENIGN LYMPH NODE, (0/1).
- BENIGN SALIVARY GLANDULAR TISSUE.

COMMENT:

See previous cases

Consultant:

ELECTRONICALLY SIGNED OUT

GROSS DESCRIPTION:

A. (R) superficial parotidectomy: The specimen is received fresh labeled, "superficial parotidectomy," and consists of a 41-gram fragment of skeletal muscle and fatty tissue measuring 7 x 6 x 4 cm. The specimen is marked with black ink and is serially sectioned revealing two candidate lymph nodes ranging in greatest dimension from 0.6 to 4 cm. Both lymph nodes have tan mottled black cut surfaces. A representative portion of the largest lymph node is submitted for tissue banking. Additional sections of the specimen are submitted for permanent section. The remaining cut surfaces shows lobulated yellow tissue. A1-A3) Larger nodule. A4) Smaller nodule. A5) Nonneoplastic tissue.

B. Parotid lymph node right: Received in formalin labeled, "right parotid lymph node," is a 1 x 0.5 x 0.4 cm irregular, tan soft tissue as well as a 0.7 x 0.5 x 0.3 cm gray-purple candidate lymph node. The specimen is submitted in toto in B1.

MICROSCOPIC DESCRIPTION:

A. Sections show two lymph nodes with effacement of architecture by sheets of malignant epithelioid cells with brisk mitoses, prominent nucleoli, pigment, and large areas of necrosis, consistent with metastatic melanoma. Perineural invasion is noted. There is scant surrounding residual lymphoid tissue. There is surrounding salivary glandular parenchyma and there is skeletal muscle at the periphery of the tissue. In both nodes there are areas of extracapsular extension with tumor cells extending into the surrounding adipose tissue and salivary glandular

[page 2 of 2]
parenchyma. There are separate nodules of malignant cells within salivary glandular parenchyma. There is lymphovascular space invasion. Melanoma is less than 1 mm from the inked tissue edge, no melanoma is identified at ink.

B. Sections show a single intraparenchymal lymph node with adjacent salivary tissue. An atypical cellular infiltrate is not identified. Negative for malignancy.

Source: NCI Genomic Data Commons file 03376e5e-0fe4-4975-9005-d1e49c35c7fd (TCGA-3N-A9WD.92AC35B1-3F7C-4062-B06F-BDA530145C88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).